Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EM-01A (Primary Tumor).

Department of Cancer Pathology

ICD-O-3

Carcinoma, squamous cell NOS
8070/3
Site CCRF Oral Cavity C06.4
path Tongue NOS C02.9
W 5/24/13

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge: Surgery and Laryngological Oncology Dept.

Physician in charge:

Clinical diagnosis (suspicion) Cancer of the tongue

Date of admission:

Material:

1) Material: oral cavity – tongue. Please mark surgical margins. Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis

Examination performed on:

Squamous cell carcinoma of the tongue

Assistant:

Pathologist:

Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Site AA discrepancy		✓

Source: NCI Genomic Data Commons file 0a4a4e16-21c4-4606-a3b4-0cc33fc0ba41 (TCGA-D6-A6EM.1CF258D1-C0B7-471A-B2DB-A0CC377AD908.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).